CCDI case PBCPFJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/b9589ccf-79b7-4794-98c6-c67d4f1897b4

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Myxofibrosarcoma: ICD-O-3 morphology code: 8811/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 10.1 years (3,672 days).

Biospecimens (3 samples)
- Sample 0DWVEH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWVEW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWVFJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
